Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A4PL, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A4PL-01A (Primary Tumor).

[page 1 of 6]
ICD0-3

Malignant Mullerian Mixed
Tumor 8950/3

SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Site: Endometrium
C54.1
12/14/12 J

Diagnosis:

A: Lymph node, left pelvic sentinel, biopsy:

- One lymph node negative for malignancy on multiple serial and three H & E stained level sections (0/1).

B: Lymph node, right periaortic, regional dissection:

- Five lymph nodes negative for malignancy (0/5).

C: Lymph node, left periaortic, regional dissection:

- Two lymph nodes negative for malignancy (0/2).

D: Uterus, cervix and bilateral adnexa, hysterectomy and bilateral salpingo-oophorectomy:

Location of tumor: Endometrium.

Histologic type: Carcinosarcoma (malignant mullerian mixed tumor).

Histologic grade (FIGO): Grade 3.

Extent of invasion: Confined to the endometrium/polypoid lesion.

Myometrial invasion: Absent.

Serosal involvement: Absent.

Cervical involvement: Absent.

Adnexal involvement: Absent.

Other sites: Pelvic washing is negative

Cervical/vaginal margin and distance: Widely negative.

Lymphovascular space invasion: Absent.

Regional lymph nodes (See parts A-C,E,F):

Total number involved: 0

Total number examined: 24

[page 2 of 6]
Other pathologic findings:

Cervix: Nabothian cysts.

Endometrium: Intraepithelial carcinoma in a background of atrophy.

Myometrium: Adenomyosis.

Ovaries: Age related changes bilaterally.

Fallopian tubes: Unremarkable bilaterally.

Tumor estrogen and progesterone receptor immunohistochemistry results: Pending, addendum to follow.

AJCC Pathologic Stage: pT1a pN0 pMX

FIGO (2008 classification) Stage grouping: IA

NOTE: These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

E: Lymph node, right pelvic, regional dissection:

- Eleven lymph nodes negative for malignancy (0/11).

F: Lymph node, left pelvic, regional dissection:

- Five lymph nodes negative for malignancy (0/5).

Intraoperative Consult Diagnosis:

Frozen section diagnosis was requested by Dr. on
from

FSA1: Sentinel lymph node, pelvic, removal

- One lymph node, no tumor seen (0/1).

Drs.

Frozen Section Pathologist:, MD

Clinical History:

-year-old female with endometrial cancer.

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "left pelvic sentinel lymph node." It holds a 1.7 x 0.8 x 0.3 cm firm tan lymph node candidate. This is cross sectioned along the long axis and

[page 3 of 6]
entirely submitted in block FSA1. Fatty tissue remains.

Container B is additionally labeled "right peri-aortic lymph nodes." It holds a 3.5 x 2.0 x 0.9 cm aggregate of bright yellow lobulated fat containing multiple lymph node candidates ranging in size from 0.9 to 2.3 cm in largest dimension.

Block Summary:

B1 - one lymph node candidate, bisected
B2,B3 - one lymph node candidate, bisected, each block
B4 - one lymph node candidate, serially sectioned
B5 - adipose tissue,

Container C is additionally labeled "left peri-aortic lymph node." It holds a 2.5 x 0.9 x 1.6 cm aggregate of yellow lobulated fat containing multiple lymph node candidates ranging in size from 0.4 to 1.1 cm in largest diameter.

Block summary:

C1 - one lymph node candidate, bisected
C2 - multiple lymph node candidates
C3 - adipose tissue,

Container D:

Adnexa: present and attached
Weight: 84.9 grams
Shape: pear shaped
Dimensions:
height: 8.5 cm
anterior to posterior width: 3.5 cm
breadth at fundus: 6.0 cm
Serosa: smooth and glistening with occasional adhesions and small fat deposits
Cervix: 1.7 x 1.5 cm with a patent cervical os measuring 0.4 cm in diameter

length of endocervical canal: 2.4 cm
ectocervix: smooth and tan with blue dye visible on the ectocervical surface
endocervix: tan and trabeculated
Endomyometrium:
length of endometrial cavity: 3.2 cm
width of endometrial cavity at fundus: 1.9 cm

[page 4 of 6]
tumor findings:

dimensions: 1.6 x 0.9 cm

appearance: dark brown, hemorrhagic and exophytic protruding into the uterus to a height of 0.6 cm

location and extent: The lesion is localized to the posterior corpus wall.

myometrial invasion: no apparent invasion

thickness of myometrial wall at deepest gross invasion: 1.2 cm

other findings or comments: none

Adnexa:

Right ovary:

dimensions: 1.1 x 0.5 x 0.3 cm

external surface: yellow/tan and smooth

cut surface: tan and firm

Right fallopian tube:

dimensions: 3.5 cm long, 0.4 cm in diameter

other findings: The surface is light tan and smooth and the lumen is patent.

Left ovary:

dimensions: 1.2 x 0.6 x 0.4 cm

external surface: yellow/tan and smooth

cut surface: tan and firm

Left fallopian tube:

dimensions: 3.9 cm long, 0.5 cm in diameter

other findings: The surface is light tan and smooth and the lumen is patent.

Lymph nodes: See Specimens A-C and E,F

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations:

Block Summary:

D1 - anterior cervix

D2 - posterior cervix

D3-D6 - endometrial lesion

D7 - anterior endomyometrium

D8 - posterior endomyometrium

D9 - right fallopian tube and ovary

D10 - left fallopian tube and ovary

Container E is additionally labeled "right pelvic lymph node."
It holds a 3.9 x 2.1 x 1.6 cm aggregate of bright yellow lobulated fat containing multiple lymph node candidates ranging in size from 0.6 to 2.1 cm in largest dimension.

Block summary:

[page 5 of 6]
E1 - multiple lymph node candidates
E2 - one lymph node candidate, serially sectioned
E3-E6 - adipose tissue,

Container F is additionally labeled "left pelvic lymph node." It holds a 4.2 x 3.6 x 2.0 cm aggregate of bright yellow lobulated fat containing multiple lymph node candidates ranging from 0.3 to 2.8 cm in largest dimension.

Block summary:

F1,F2 - multiple lymph node candidates
F3 - one lymph node candidate, bisected, and one lymph node candidate, inked black and not bisected
F4,F5 - one lymph node candidate, serially sectioned
F6,F7 - adipose tissue,

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

Procedures/Addenda:

Addendum

Addendum

The following addendum is issued to report the results of estrogen and progesterone receptor immunohistochemical studies.

Results:

Estrogen receptor (, clone SP1): Weakly positive (1+, 5%).

Progesterone receptor . clone 1E2): Weakly positive (1-2+, 5%).

Site: Endometrium

Performed on block: D5

Fixation: 10% neutral buffered formalin

Fixation time: 6-48 hours

Reference range:

Estrogen receptor and progesterone receptor: <1%=NEGATIVE, 1-10% WEAK POSITIVE, >10% POSITIVE

[page 6 of 6]
Addendum Comment

Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR) or research use only (RUO) reagents. These were developed and have performance characteristics determined by . These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

[illegible]

Source: NCI Genomic Data Commons file 3f7833e3-88d9-4e72-a51a-778e0347cffb (TCGA-N8-A4PL.150B8690-8425-46A2-A818-B8C2E145790F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).